Somatic mutation profile of tumor specimen 0DNJBC from CCDI case PBCBSB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 8.9 years (3,266 days).
Specimen 0DNJBC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a8214bf-0717-470a-a4c0-b540190051e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNJA6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aec3978e-a415-4ae4-8110-e55e4e9269d2

The open-access MAF lists 119 somatic variants for this specimen: 77 protein-altering or splice-affecting, 20 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 20, Intron 12, Nonsense Mutation 5, 3'UTR 5, Frame Shift Del 4, Splice Site 2, 3'Flank 2, RNA 2, 5'UTR 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1634A>G p.Y545C (on ENST00000281708 / NM_001349798.2; = p.Y465C on NM_018315.5) | Missense Mutation (SNP) | VAF 78/195 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560758208, COSV55890892, COSV55908001, COSV55914345; called by muse, mutect2, varscan2
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 253/547 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 98/211 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX12 | c.1454G>C p.R485T | Missense Mutation (SNP) | VAF 104/242 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs200671464; called by muse, mutect2, varscan2
- AMBRA1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 109/394 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs754594941; called by muse, mutect2, varscan2
- ANO8 | c.2758C>T p.R920W | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1293469887; called by muse, mutect2, varscan2
- CCDC30 | c.1729G>A p.E577K (on ENST00000340612; = p.E534K on NM_001080850.3) | Missense Mutation (SNP) | VAF 185/642 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59609543; called by muse, mutect2, varscan2
- DNTTIP1 | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 204/1136 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs990520848; called by muse, mutect2, varscan2
- FAM170A | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 118/388 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1234417989; called by muse, mutect2, varscan2
- FBXW7 | c.1876G>T p.A626S (on ENST00000281708 / NM_001349798.2; = p.A546S on NM_018315.5) | Missense Mutation (SNP) | VAF 157/387 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55920687, COSV55929339; called by muse, mutect2, varscan2
- HLA-DPA1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 281/446 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs371532700; called by muse, mutect2
- IGSF9B | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58066285; called by muse, mutect2, varscan2
- LILRA1 | c.71-1G>T p.X24_splice | Splice Site (SNP) | VAF 27/125 reads (22%) | catalogued as COSV52183602; called by muse, mutect2, varscan2
- MAGI2 | c.2119A>G p.S707G | Missense Mutation (SNP) | VAF 134/609 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.182); catalogued as COSV62647366; called by muse, mutect2, varscan2
- MTERF1 | c.675G>T p.L225F | Missense Mutation (SNP) | VAF 241/971 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV61099003; called by muse, mutect2, varscan2
- NPPA | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 140/473 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377057675, COSV56737928; called by muse, mutect2, varscan2
- ODF3L2 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1053675073; called by muse, mutect2, varscan2
- OR4A5 | c.532A>G p.M178V | Missense Mutation (SNP) | VAF 135/499 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.029); catalogued as rs1311262826; called by muse, mutect2, varscan2
- OR8K1 | c.533A>C p.N178T | Missense Mutation (SNP) | VAF 130/549 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99687060; called by muse, mutect2, varscan2
- PAXIP1 | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 110/448 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.874); catalogued as rs368471881; called by muse, mutect2, varscan2
- PI16 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 116/256 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760764623, COSV101028622; called by muse, mutect2
- PLXNC1 | c.4198dup p.I1400Nfs*5 | Frame Shift Ins (INS) | VAF 224/770 reads (29%) | catalogued as rs1555212337; called by mutect2, varscan2
- SMPDL3B | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 86/329 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1045144363; called by muse, mutect2, varscan2
- SPATA21 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1443565098; called by muse, mutect2, varscan2
- TLE4 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 111/253 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1233699178; called by muse, mutect2, varscan2
- TMPRSS13 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV70626150; called by muse, mutect2, varscan2
- TRAM1L1 | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 128/335 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs1274507977; called by muse, mutect2, varscan2
- ZNF615 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 257/935 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs972573339, COSV100943879; called by muse, mutect2, varscan2
- ADGRL4 | c.1138A>T p.M380L | Missense Mutation (SNP) | VAF 228/783 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADGRV1 | c.18593C>T p.S6198F | Missense Mutation (SNP) | VAF 113/368 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADRB2 | c.669T>A p.F223L | Missense Mutation (SNP) | VAF 146/502 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AP5B1 | c.2377G>T p.G793C | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF10 | c.3955A>G p.K1319E (on ENST00000398564; = p.K1294E on NM_014629.4) | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ASIC3 | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- BCL6 | c.913A>T p.R305* | Nonsense Mutation (SNP) | VAF 87/266 reads (33%) | called by muse, mutect2, varscan2
- BCOR | c.1982_1988del p.P661Lfs*6 | Frame Shift Del (DEL) | VAF 90/96 reads (94%) | called by mutect2, varscan2
- CBLL1 | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 184/790 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CCDC190 | c.698G>C p.C233S | Missense Mutation (SNP) | VAF 133/541 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CEP97 | c.662del p.P221Rfs*8 | Frame Shift Del (DEL) | VAF 188/568 reads (33%) | called by mutect2, varscan2
- COL24A1 | c.2948C>A p.T983K | Missense Mutation (SNP) | VAF 99/561 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- EAF2 | c.731C>T p.T244I | Missense Mutation (SNP) | VAF 179/632 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ETNK2 | c.500G>C p.R167P | Missense Mutation (SNP) | VAF 93/346 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- EXOC6 | c.284C>G p.T95S | Missense Mutation (SNP) | VAF 200/497 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FABP2 | c.68-1G>C p.X23_splice | Splice Site (SNP) | VAF 190/358 reads (53%) | called by muse, mutect2, varscan2
- GABRA2 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 247/652 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.238); called by muse, mutect2
- GLB1L3 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 127/474 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GOLGA2 | c.867C>G p.Y289* | Nonsense Mutation (SNP) | VAF 99/254 reads (39%) | called by muse, mutect2, varscan2
- ITGA1 | c.320C>G p.T107R | Missense Mutation (SNP) | VAF 253/763 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ITPR1 | c.3877G>A p.V1293I (on ENST00000354582; = p.V1278I on NM_002222.7) | Missense Mutation (SNP) | VAF 192/405 reads (47%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- JAG2 | c.1805C>G p.A602G | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2
- KDM7A | c.1477C>A p.P493T | Missense Mutation (SNP) | VAF 132/662 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KLK7 | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2B | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KRT17 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 118/285 reads (41%) | called by muse, mutect2, varscan2
- MIA3 | c.3711T>A p.Y1237* | Nonsense Mutation (SNP) | VAF 174/591 reads (29%) | called by muse, mutect2, varscan2
- MRC1 | c.2140T>A p.W714R | Missense Mutation (SNP) | VAF 248/511 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUSK | c.2108T>C p.L703P | Missense Mutation (SNP) | VAF 140/319 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH4 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ODR4 | c.147del p.E51Rfs*38 | Frame Shift Del (DEL) | VAF 267/833 reads (32%) | called by mutect2, varscan2
- OR2A2 | c.765G>C p.M255I | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR7G2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 89/474 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR8S1 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 165/602 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- PDIA6 | c.653del p.A218Efs*104 | Frame Shift Del (DEL) | VAF 102/399 reads (26%) | called by mutect2, varscan2
- POSTN | c.814T>A p.F272I | Missense Mutation (SNP) | VAF 246/595 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PPIF | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 136/310 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ROS1 | c.3307G>T p.A1103S | Missense Mutation (SNP) | VAF 235/722 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, varscan2
- RP1 | c.2944A>C p.T982P | Missense Mutation (SNP) | VAF 122/525 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RWDD2A | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 160/536 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO1A2 | c.1723T>A p.C575S | Missense Mutation (SNP) | VAF 204/736 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX31 | c.1243A>G p.S415G | Missense Mutation (SNP) | VAF 242/1296 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- SULF1 | c.742A>C p.S248R | Missense Mutation (SNP) | VAF 110/473 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- THSD7B | c.1376G>T p.R459I | Missense Mutation (SNP) | VAF 114/353 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TRAM1L1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 128/334 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TTC23L | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 366/990 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TTC26 | c.1463A>G p.E488G | Missense Mutation (SNP) | VAF 252/1017 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USB1 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 109/245 reads (44%) | called by muse, mutect2, varscan2
- ZNF649 | c.291A>G p.I97M | Missense Mutation (SNP) | VAF 238/1043 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP45 | c.303C>T p.G101= | Silent (SNP) | VAF 45/192 reads (23%) | catalogued as rs1435395008; called by muse, mutect2, varscan2
- ARHGEF40 | c.2859G>A p.Q953= | Silent (SNP) | VAF 44/231 reads (19%) | called by muse, mutect2, varscan2
- BCL11B | c.1749G>A p.A583= (on ENST00000357195 / NM_001282237.2; = p.A512= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/216 reads (28%) | catalogued as rs760702497, COSV61735564; called by muse, varscan2
- BCL9L | c.4047C>T p.P1349= | Silent (SNP) | VAF 81/275 reads (29%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.675G>T p.L225= | Silent (SNP) | VAF 72/212 reads (34%) | called by muse, mutect2, varscan2
- CD4 | c.1164C>G p.P388= | Silent (SNP) | VAF 51/166 reads (31%) | called by muse, mutect2, varscan2
- CTPS1 | c.1197C>T p.C399= | Silent (SNP) | VAF 112/452 reads (25%) | called by muse, mutect2, varscan2
- DYRK3 | c.654G>T p.G218= | Silent (SNP) | VAF 127/431 reads (29%) | called by muse, mutect2, varscan2
- GAB4 | c.1554C>T p.Y518= | Silent (SNP) | VAF 102/359 reads (28%) | catalogued as rs749685093; called by muse, mutect2, varscan2
- GLCE | c.1200C>G p.A400= | Silent (SNP) | VAF 104/244 reads (43%) | called by muse, mutect2, varscan2
- GLIS1 | c.1791C>T p.D597= | Silent (SNP) | VAF 86/270 reads (32%) | called by muse, mutect2, varscan2
- GRK4 | c.330C>T p.F110= (on ENST00000398052 / NM_182982.3; = p.F78= on NM_005307.3) | Silent (SNP) | VAF 150/450 reads (33%) | called by muse, mutect2
- HAS1 | c.1557C>T p.R519= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as rs751458232; called by muse, mutect2, varscan2
- HAS1 | c.1290G>A p.A430= | Silent (SNP) | VAF 76/354 reads (21%) | catalogued as rs1280520184, COSV55786934, COSV55790351; called by muse, mutect2, varscan2
- MYH1 | c.4818T>C p.D1606= | Silent (SNP) | VAF 183/409 reads (45%) | catalogued as COSV56854352; called by muse, mutect2, varscan2
- POMC | c.540G>A p.L180= | Silent (SNP) | VAF 66/166 reads (40%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.2601G>A p.L867= | Silent (SNP) | VAF 106/549 reads (19%) | called by muse, mutect2, varscan2
- SBK1 | c.756G>A p.P252= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs55837875; called by muse, mutect2, varscan2
- TAMALIN | c.810C>T p.R270= | Silent (SNP) | VAF 55/201 reads (27%) | catalogued as COSV53337929; called by muse, mutect2, varscan2
- WTIP | c.1158C>T p.C386= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as rs780001532; called by muse, mutect2, varscan2
- AC092681.1 | chr7:149891106 C>T | 3'Flank (SNP) | VAF 29/204 reads (14%) | catalogued as rs1330721166; called by muse, mutect2, varscan2
- ADAM10 | c.1804+19C>A | Intron (SNP) | VAF 113/283 reads (40%) | called by muse, mutect2, varscan2
- ALAD | c.114-169C>A | Intron (SNP) | VAF 61/124 reads (49%) | called by muse, mutect2, varscan2
- AP4M1 | chr7:100110203 G>A | 3'Flank (SNP) | VAF 95/492 reads (19%) | catalogued as rs191382984; called by muse, mutect2, varscan2
- ARL15 | c.253+16T>C | Intron (SNP) | VAF 174/676 reads (26%) | called by muse, mutect2, varscan2
- B3GAT1-DT | n.852G>A | RNA (SNP) | VAF 63/220 reads (29%) | catalogued as rs916349669; called by muse, mutect2, varscan2
- C11orf52 | c.32+14A>C | Intron (SNP) | VAF 102/355 reads (29%) | called by muse, mutect2, varscan2
- C6orf52 | c.271-1683T>C | Intron (SNP) | VAF 93/221 reads (42%) | called by muse, mutect2, varscan2
- CDK20 | c.844-51G>A | Intron (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- CPZ | c.122-49G>A | Intron (SNP) | VAF 39/91 reads (43%) | catalogued as rs774760742; called by muse, mutect2, varscan2
- CRIP2 | c.406+21C>T | Intron (SNP) | VAF 60/211 reads (28%) | called by muse, mutect2, varscan2
- DOT1L | c.1558-26A>G | Intron (SNP) | VAF 64/393 reads (16%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.5050-13G>T | Intron (SNP) | VAF 97/393 reads (25%) | called by muse, mutect2, varscan2
- FGF14 | c.*7310T>C | 3'UTR (SNP) | VAF 90/216 reads (42%) | called by muse, mutect2, varscan2
- GGTLC2 | c.*76G>C | 3'UTR (SNP) | VAF 29/97 reads (30%) | called by muse, mutect2, varscan2
- HCST | c.43+74C>T | Intron (SNP) | VAF 22/76 reads (29%) | catalogued as rs901460285, COSV52888688; called by muse, mutect2, varscan2
- HSP90B1 | c.*73C>T | 3'UTR (SNP) | VAF 18/535 reads (3%) | called by muse, mutect2
- NTM-AS1 | n.1740C>A | RNA (SNP) | VAF 62/187 reads (33%) | called by mutect2, varscan2
- RACK1 | c.282-65A>T | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- RB1CC1 | c.-22C>T | 5'UTR (SNP) | VAF 96/461 reads (21%) | catalogued as rs1326573609; called by muse, mutect2, varscan2
- RBFA | c.*48C>G | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- SYNGR4 | c.*47G>T | 3'UTR (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2, varscan2
